Surgical pathology report (de-identified scan), TCGA case TCGA-VP-A876, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Washington University, specimen TCGA-VP-A876-01A (Primary Tumor).

[page 1 of 4]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

ICD O-3
Adenocarcinoma, acinar
8140/3
Site: Prostate NOS
061.9
11/21/13

SURGICAL PATHOLOGY REPORT
FINAL

Patient Name: [REDACTED]
Address: [REDACTED] Service: [REDACTED]
[REDACTED] Location
Gender: M MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type:

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

PROSTATE, RADICAL EXCISION

- ADENOCARCINOMA, GLEASON GRADE 3+5, INVOLVING BOTH LOBES, T2C/M0/MX (SEE
SYNOPTIC)

- TUMOR INVOLVES APPROXIMATELY 25% OF PROSTATIC TISSUE
- MARGINS FREE OF TUMOR
- PERINEURAL INVASION SEEN
- SEMINAL VESICLES FREE OF TUMOR
- HIGH GRADE PIN, FOCAL

LYMPH NODE, RIGHT PELVIC, EXCISION

- THREE LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (0/3)

LYMPH NODE, LEFT PELVIC, EXCISION

- NINE LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY (0/9)

By this signature, I attest that the above diagnosis is
based upon my personal
examination of the slides (and/or other material indicated in the
diagnosis).

***Report Electronically Reviewed and Signed Out By
Diagnosis Comment:

A. PROSTATE:

B. PROSTATE:

C. LYMPH NODE, LEFT PELVIC:

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and is interpreted
as: "Called to pickup 'prostate', measuring 5 x 4.8 x 3.3 cm with attached
seminal vesicles (1.5 x 1.1 x 0.7 and 1.8 x 1.3 x 0.6 cm on the right and left,
respectively) and attached vas deferens (0.8 x 0.4 and 0.9 x 0.4 cm on the right
and left, respectively), weighing 56 grams in total. Inked black. Tissue taken
for tumor bank. All for permanents," by

[page 2 of 4]
Patient Name: [REDACTED]

Microscopic Description and Comment:
{Not Entered}

History:

The patient is a [REDACTED] man with prostate adenocarcinoma. Operative procedure: Radical retropubic prostatectomy with bilateral pelvic lymph node excision.

Specimen(s) Received:

A: PROSTATE

B: PROSTATE

C: LYMPH NODE, LEFT PELVIC

Gross Description

Received are three formalin-filled containers, each labeled "[REDACTED]". The first container is labeled "prostate." It holds a 56 gram radical prostatectomy specimen consisting of: a prostate measuring 3.5 cm from inferior to superior, 3.5 cm from anterior to posterior, and 4.7 cm from left to right; an attached right seminal vesicle measuring 2.0 x 1.5 x 1.0 cm; an attached left seminal vesicle measuring 2.0 x 1.3 x 1.0 cm; an attached right vas deferens measuring 1.5 x 0.5 x 0.4 cm; and an attached left vas deferens measuring 2.2 x 0.5 x 0.4 cm. The specimen has been previously inked black and a section has been taken from each prostatic lobe, measuring 2.6 x 0.2 x 0.8 cm and 2.5 x 0.4 x 0.8 cm on right and left, respectively. On section, the parenchyma of the prostate is tan-pink and grossly unremarkable. The walls of the seminal vesicles are tan and are lined by tan-brown epithelium surrounding lumina with moderate amounts of mucoid material. Labeled A1 - bladder neck shaved margin; A2, A3 - left apical radial margin; A4, A5 - right apical radial margin; A6, A7 - left apex; A8, A9 - left base; A10, A11 - right apex; A12, A13 - right base; A14 - left seminal vesicle; A15 - right seminal vesicle. Jar 2. The second container is labeled "right pelvic lymph node." It holds a fragment of fibrofatty tissue measuring 5.0 x 2.3 x 1.2 cm. On section, the specimen shows tan, purple-tan and yellow fat-infiltrated lymphoid tissue. Labeled B1, B2. Jar 1. The third container is labeled "left pelvic lymph node." It holds a fragment of fibrofatty tissue measuring 4.5 x 2.5 x 1.0 cm. On section, the specimen shows purple-tan and yellow fat infiltrated lymphoid tissue. Labeled C. Jar 1.

A. PROSTATE:

B. PROSTATE:

C. LYMPH NODE, LEFT PELVIC:

SYNOPTIC WORKSHEET - PROSTATE CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The tumor type is adenocarcinoma, acinar type

INTRAGLANDULAR TUMOR EXTENT

The intraglandular tumor extent (reported as percent of prostate gland involved by carcinoma) = 25% CRUDE VISUAL ESTIMATE

GLEASON'S GRADE

The Gleason's Grade is 3+5

[page 3 of 4]
Patient Name: [REDACTED]

TUMOR LOCATION

The location of the tumor involves the

- right base
- right apex
- left base
- left apex

PERINEURAL INVASION

Perineural Invasion is identified

VASCULAR INVASION

Vascular Invasion is not identified

EXTRAPROSTATIC EXTENSION

Extraprostatic (extracapsular) extension is absent

SEMINAL VESICLES

Seminal vesicles are free of tumor

SAMPLED SPECIMEN MARGINS

All sampled surgical margins are free of tumor

NON-NEOPLASTIC PROSTATE

The non-neoplastic prostate shows PIN, high grade, focal

METASTATIC LYMPH NODES

The lymph nodes are as follows (expressed as the number of metastatic nodes in relation to the total number of nodes examined)

- Right pelvic: 0/3
- Left pelvic: 0/9

PRIMARY TUMOR (T)

Tumor involves both lobes (T2c)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis (N0)

DISTANT METASTASIS

Distant metastasis cannot be assessed (not evaluated by any modality) (MX)

STAGE GROUPING

T2C/N0/MX/GLEASON SCORE 3+5 (AT LEAST STAGE II)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS) _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason score on the initial pathology report is $3+5=8$	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Top slide review Gleason score is $3+4=7$	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The top slide review showed a different Gleason score from the Gleason score on the initial Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Review

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 1ddcc36d-b737-4c62-86ce-5ea4622cd1f8 (TCGA-VP-A876.A10667AF-8A71-492D-B71C-95160DE9EEE6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).